Gene-level copy-number profile of tumor specimen TCGA-66-2767-01A from TCGA case TCGA-66-2767, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.7 years (22,888 days).
Specimen TCGA-66-2767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8d1ef214-b22b-4edb-9fd6-d790774dbe7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2767-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/513356e6-267c-426b-8c81-479fccc1f8d2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 573; copy number 2: 13,197; copy number 3: 13,419; copy number 4: 14,389; copy number 5: 12,076; copy number 6: 3,009; copy number 8: 1,612; copy number 9: 363; copy number 10: 851; copy number 12: 133; copy number 13: 16; copy number 15: 19; copy number 19: 3; copy number 20: 5; copy number 21: 8; copy number 36: 36; copy number 40: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2767-01A-01D-0844-01): tumor purity 0.27, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr9:14,475–3,053,408, 45 genes (within-gene range 0–9): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,487 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:3,181,342–7,175,648, 86 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:43,063,637–43,673,393, 15 genes, copy number 13–21: AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG.
- chr11:43,581,394–43,581,483, 1 gene, copy number 13: MIR129-2.
- chr11:69,147,228–70,436,584, 38 genes, copy number 19–36: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 36: AP001271.1.
- chr12:66,767–37,576,384, 851 genes, copy number 10 (broad region; genes not listed).
- chr15:66,919,811–67,542,604, 12 genes, copy number 13–20 (within-gene range 13–34): AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1.
- chr15:100,547,765–100,919,391, 19 genes, copy number 15 (within-gene range 3–15): AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2.
- chr19:30,553,956–41,018,398, 449 genes, copy number 9–40 (broad region; genes not listed).
- chr21:17,210,469–17,792,523, 15 genes, copy number 9: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1.

Autosomal genes at a single copy (total copy number 1): 566. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
